Somatic mutation profile of tumor specimen TCGA-BJ-A0Z9-01A (aliquot TCGA-BJ-A0Z9-01A-11D-A10S-08) from TCGA case TCGA-BJ-A0Z9, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary carcinoma, columnar cell; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage III; Age at diagnosis: 57.7 years (21,061 days).
Specimen TCGA-BJ-A0Z9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9f9f6919-86a4-427f-9c2b-b154e866073e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BJ-A0Z9-10A (Blood Derived Normal), aliquot TCGA-BJ-A0Z9-10A-01D-A10S-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/19abe9b9-079c-4201-aafb-4858963b8328

The open-access MAF lists 20 somatic variants for this specimen: 17 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 13, Silent 3, Nonsense Mutation 3, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- APOB | c.9046G>T p.E3016* | Nonsense Mutation (SNP) | VAF 20/68 reads (29%) | catalogued as COSV51936143; called by muse, mutect2, varscan2
- ARMCX2 | c.587G>T p.G196V | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0); catalogued as COSV57530172; called by muse, mutect2, varscan2
- CCAR2 | c.2524G>T p.E842* | Nonsense Mutation (SNP) | VAF 5/21 reads (24%) | catalogued as COSV52384668; called by muse, mutect2
- CFAP300 | c.662A>C p.K221T | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as rs1312875364, COSV71570810; called by muse, mutect2, varscan2
- CRYBG1 | c.3532A>T p.M1178L | Missense Mutation (SNP) | VAF 38/88 reads (43%) | SIFT tolerated (0.4); PolyPhen benign (0.017); catalogued as COSV64812276; called by muse, mutect2, varscan2
- KCNV2 | c.986G>A p.R329H | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.011); catalogued as rs1197568554, COSV66056201, COSV66056322; called by muse, mutect2, varscan2
- PDZD2 | c.3887C>A p.A1296E | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.637); catalogued as COSV56858828; called by muse, mutect2, varscan2
- PLEC | c.9416G>A p.R3139Q (on ENST00000322810 / NM_201380.4; = p.R3029Q on NM_000445.5) | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs782565838, COSV59638251; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PTH2R | c.345A>C p.L115F | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.694); catalogued as COSV55916298; called by muse, mutect2, varscan2
- PXDNL | c.1571T>C p.V524A | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.51); PolyPhen benign (0.101); catalogued as rs1352238132, COSV62487689; called by muse, mutect2
- SLC26A9 | c.1519C>G p.Q507E | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.061); catalogued as COSV61602964, COSV61603348; called by muse, mutect2, varscan2
- SPATS1 | c.634C>T p.P212S | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV55823375; called by muse, mutect2, varscan2
- TAX1BP1 | c.1884T>A p.N628K | Missense Mutation (SNP) | VAF 40/116 reads (34%) | SIFT tolerated (0.92); PolyPhen benign (0.003); catalogued as COSV55293071, COSV55295334; called by muse, mutect2, varscan2
- ZNF467 | c.307C>T p.Q103* | Nonsense Mutation (SNP) | VAF 20/52 reads (38%) | catalogued as COSV57373193; called by muse, mutect2, varscan2
- SMPDL3B | c.949G>A p.A317T | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.743); called by muse, mutect2
- USP9X | c.1890del p.Y630* | Frame Shift Del (DEL) | VAF 25/85 reads (29%) | called by mutect2, pindel*, varscan2*
- SIGLEC11 | c.1692C>T p.A564= | Silent (SNP) | VAF 30/69 reads (43%) | catalogued as COSV68567706; called by muse, mutect2, varscan2
- VCAM1 | c.1650C>A p.L550= | Silent (SNP) | VAF 8/65 reads (12%) | catalogued as COSV54119541; called by muse, mutect2, varscan2
- VPS53 | c.1452A>G p.Q484= (on ENST00000571805 / NM_001366253.2; = p.Q455= on NM_018289.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/70 reads (9%) | catalogued as rs370664941; called by muse, mutect2
